Somatic mutation profile of tumor specimen TCGA-VS-A953-01A (aliquot TCGA-VS-A953-01A-11D-A387-09) from TCGA case TCGA-VS-A953, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 63.7 years (23,277 days).
Specimen TCGA-VS-A953-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aaee5060-0847-4b3f-be8c-a0d3ab06f032.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A953-10A (Blood Derived Normal), aliquot TCGA-VS-A953-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd89859b-aaf3-45bf-89a0-6dcb457bfcf0

The open-access MAF lists 422 somatic variants for this specimen: 291 protein-altering or splice-affecting, 118 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 256, Silent 118, Nonsense Mutation 24, Splice Region 5, Intron 5, RNA 4, Splice Site 3, 5'UTR 2, 3'Flank 2, Frame Shift Ins 1, Nonstop Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMPR1A | c.64C>T p.Q22* | Nonsense Mutation (SNP) | VAF 31/35 reads (89%) | catalogued as rs1554886821, COSV100923584; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GRIN2A | c.1507C>T p.Q503* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as rs1555494699, COSV100410171; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MEGF10 | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs387907074, CM121750, COSV57250918, COSV99174792; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 72/80 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCF3 | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99035317; called by muse, mutect2, varscan2
- ACKR1 | c.530C>A p.A177D | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV100929592; called by muse, mutect2, varscan2
- ACSM2A | c.296G>C p.G99A (on ENST00000219054; = p.G20A on NM_001308169.2) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV99525348; called by muse, mutect2, varscan2
- ADGRE3 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.547); catalogued as rs763019388, COSV99506306; called by muse, mutect2, varscan2
- ADGRL1 | c.2545G>C p.E849Q (on ENST00000340736 / NM_001008701.3; = p.E844Q on NM_014921.5) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.04); catalogued as COSV100529585; called by muse, mutect2, varscan2
- ADM | c.215A>G p.D72G | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.478); catalogued as COSV99534266; called by muse, mutect2, varscan2
- AGPAT3 | c.840G>C p.E280D | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV99377538; called by muse, mutect2
- AHNAK | c.4792G>C p.D1598H | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99947967; called by muse, mutect2, varscan2
- ANK2 | c.5393C>T p.P1798L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); catalogued as COSV100002149; called by muse, mutect2, varscan2
- ANK2 | c.8257G>A p.E2753K | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.023); catalogued as COSV100002152; called by muse, mutect2, varscan2
- ANKRD12 | c.4838C>T p.S1613F | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.365); catalogued as COSV100041512; called by muse, mutect2, varscan2
- ANKRD13D | c.*1375C>T | Splice Region (SNP) | VAF 16/26 reads (62%) | catalogued as COSV57383983, COSV57385399; called by muse, varscan2
- APOD | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.23); catalogued as rs5954; called by muse, mutect2, varscan2
- ARHGAP4 | c.1256C>G p.S419* | Nonsense Mutation (SNP) | VAF 14/27 reads (52%) | catalogued as COSV100604084; called by muse, mutect2, varscan2
- ARHGEF7 | c.2455G>C p.E819Q (on ENST00000646102 / NM_001354046.1; = p.E603Q on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.223); catalogued as COSV99521698; called by muse, mutect2, varscan2
- ARID2 | c.4466C>G p.S1489* | Nonsense Mutation (SNP) | VAF 18/35 reads (51%) | catalogued as COSV57603604; called by muse, mutect2, varscan2
- ASIC2 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.142); catalogued as COSV100726564; called by muse, mutect2, varscan2
- ATG10 | c.205C>G p.L69V | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.115); catalogued as COSV99966968; called by muse, mutect2, varscan2
- ATP6V0A1 | c.40C>T p.Q14* | Nonsense Mutation (SNP) | VAF 31/66 reads (47%) | catalogued as COSV99231165; called by muse, mutect2, varscan2
- ATRX | c.2551G>A p.E851K | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.339); catalogued as COSV100970935, COSV64882913; called by muse, mutect2, varscan2
- BCORL1 | c.1624G>C p.D542H | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54388958, COSV99499855; called by muse, mutect2, varscan2
- BRSK1 | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV100442380; called by muse, mutect2, varscan2
- CAMK2G | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV99989931, COSV99990483; called by muse, mutect2, varscan2
- CAPZA1 | c.531G>A p.W177* | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as COSV99583251; called by muse, mutect2, varscan2
- CAPZA2 | c.273G>C p.K91N | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV100753932, COSV63266023; called by muse, mutect2, varscan2
- CARNS1 | c.2206C>G p.L736V | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.787); catalogued as COSV100322061; called by muse, mutect2, varscan2
- CCDC105 | c.627G>A p.M209I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.243); catalogued as COSV99479936; called by muse, mutect2
- CCDC181 | c.785C>G p.S262C | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.855); catalogued as COSV100890340; called by muse, mutect2, varscan2
- CCDC38 | c.1256G>C p.G419A | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100717703; called by muse, mutect2, varscan2
- CCDC88A | c.758T>C p.L253P | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs113224565, COSV99710625; called by muse, mutect2, varscan2
- CCNDBP1 | c.281C>G p.A94G | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.36); PolyPhen benign (0.098); catalogued as COSV99543693; called by muse, mutect2, varscan2
- CDH11 | c.1466C>T p.A489V | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV99218760; called by muse, mutect2, varscan2
- CELF1 | c.1391G>A p.G464D (on ENST00000358597 / NM_001376422.1; = p.G460D on NM_006560.4 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100136988; called by muse, mutect2, varscan2
- CENPB | c.1612G>C p.E538Q | Missense Mutation (SNP) | VAF 40/61 reads (66%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100713482; called by muse, mutect2, varscan2
- CEP250 | c.2452G>A p.E818K | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV100698987; called by muse, mutect2, varscan2
- CFAP58 | c.1864G>A p.D622N | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as COSV100866119; called by muse, mutect2, varscan2
- CFAP61 | c.1849C>T p.P617S | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99845328; called by muse, mutect2, varscan2
- CHMP1B | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV99303690; called by muse, mutect2, varscan2
- CIC | c.2216C>G p.S739* | Nonsense Mutation (SNP) | VAF 10/57 reads (18%) | catalogued as COSV99359752; called by muse, mutect2, varscan2
- CIC | c.3082A>G p.T1028A | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV99359754; called by muse, mutect2, varscan2
- CILP | c.1833G>C p.Q611H | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.689); catalogued as COSV99973542; called by muse, mutect2, varscan2
- CLASP2 | c.2159A>G p.N720S | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs938232578, COSV100223626; called by muse, mutect2, varscan2
- CNTN1 | c.2195G>A p.R732K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.963); catalogued as COSV100751532; called by muse, mutect2, varscan2
- COIL | c.984G>C p.L328F | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV53594570; called by muse, mutect2, varscan2
- COL11A2 | c.874C>G p.Q292E | Missense Mutation (SNP) | VAF 76/149 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs766136290, COSV100554155; called by muse, mutect2, varscan2
- COL21A1 | c.871G>A p.V291I | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as COSV55159995, COSV99779038; called by muse, mutect2, varscan2
- COPB2 | c.712C>T p.H238Y | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100300689; called by muse, mutect2, varscan2
- COQ5 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99942277, COSV99942347; called by muse, varscan2
- COQ5 | c.250G>C p.D84H | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99942350; called by muse, varscan2
- CPM | c.4G>C p.D2H | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV100615119; called by muse, mutect2, varscan2
- CPNE3 | c.1015G>A p.D339N | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as rs1266507342, COSV99547747; called by muse, mutect2
- CREBBP | c.3914+2T>C p.X1305_splice | Splice Site (SNP) | VAF 19/29 reads (66%) | catalogued as COSV99270489; called by muse, mutect2, varscan2
- CRHBP | c.706G>T p.G236C | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99169498; called by muse, mutect2
- CTTNBP2 | c.1352G>C p.R451T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV99354179; called by muse, mutect2, varscan2
- CYP2B6 | c.985G>C p.E329Q | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV100137596; called by muse, mutect2, varscan2
- CYP2C9 | c.670G>C p.D224H | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.021); catalogued as COSV99582805; called by muse, mutect2, varscan2
- CYP4F22 | c.380C>G p.P127R | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV99512863; called by muse, varscan2
- DHPS | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV99269639; called by muse, mutect2, varscan2
- DIP2B | c.4163C>G p.S1388C | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99998696; called by muse, mutect2, varscan2
- DMD | c.5653C>T p.Q1885* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as CM098423, COSV100820294; called by muse, mutect2, varscan2
- DNAH2 | c.12409C>T p.Q4137* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | catalogued as COSV101209419; called by muse, mutect2, varscan2
- DNAJC13 | c.3661G>A p.D1221N | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99607467; called by muse, mutect2, varscan2
- DRC1 | c.1599C>T p.S533= | Splice Region (SNP) | VAF 9/26 reads (35%) | catalogued as rs377416255; called by muse, mutect2, varscan2
- ELL3 | c.981G>T p.R327S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs772702286, COSV100082607; called by muse, mutect2, varscan2
- ENPEP | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1298528080, COSV54454883, COSV99487689; called by muse, mutect2, varscan2
- EPHA10 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.213); catalogued as COSV100139990; called by muse, mutect2, varscan2
- EPHA4 | c.2323C>A p.P775T | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV56036496, COSV99916775; called by muse, mutect2, varscan2
- EPS8 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV99843286; called by muse, mutect2, varscan2
- ERBIN | c.3515G>C p.R1172T | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV99397082; called by muse, mutect2, varscan2
- ETF1 | c.1168G>C p.E390Q | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.123); catalogued as COSV100860191; called by muse, mutect2, varscan2
- EVL | c.1059G>C p.K353N (on ENST00000402714 / NM_001330221.2; = p.K355N on NM_016337.3) | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.95); catalogued as COSV101233084; called by muse, mutect2, varscan2
- F11 | c.1641G>C p.K547N | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as COSV53002525; called by muse, mutect2, varscan2
- F2 | c.225G>C p.E75D | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1015664856, COSV100319559; called by muse, mutect2
- FAAH2 | c.1036C>G p.Q346E | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as COSV66509314; called by muse, mutect2, varscan2
- FANCM | c.4123G>T p.E1375* | Nonsense Mutation (SNP) | VAF 4/50 reads (8%) | catalogued as COSV99951161, COSV99951550; called by muse, mutect2
- FAT3 | c.13544C>T p.S4515L | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs768827430, COSV53126641; called by muse, mutect2, varscan2
- FBH1 | c.2734G>A p.E912K (on ENST00000362091 / NM_178150.3; = p.E963K on NM_032807.4) | Missense Mutation (SNP) | VAF 32/35 reads (91%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.597); catalogued as COSV100758786; called by muse, mutect2, varscan2
- FBXO5 | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs199732439, COSV99999855; called by muse, mutect2, varscan2
- FHL1 | c.36T>A p.D12E | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV100600798; called by muse, mutect2, varscan2
- FLG2 | c.5447C>T p.S1816L | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.222); catalogued as COSV101165944; called by muse, mutect2, varscan2
- FSHR | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100437362; called by muse, mutect2, varscan2
- FUT3 | c.1085G>C p.*362Sext*105 | Nonstop Mutation (SNP) | VAF 33/84 reads (39%) | catalogued as COSV99744691; called by muse, mutect2, varscan2
- GABBR1 | c.957C>G p.F319L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.651); catalogued as COSV100589779; called by muse, mutect2, varscan2
- GAL | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV99681833; called by muse, mutect2, varscan2
- GALNT16 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.141); catalogued as COSV100545994; called by muse, mutect2, varscan2
- GOLGA4 | c.1543C>T p.L515F | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100728970; called by muse, mutect2, varscan2
- GPC1 | c.1542G>C p.L514F | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.214); catalogued as COSV99882973; called by muse, mutect2, varscan2
- GRIN3A | c.1384A>C p.N462H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100701574; called by muse, mutect2, varscan2
- GRM1 | c.1542G>A p.M514I | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV51321645, COSV99266757; called by muse, mutect2, varscan2
- GRM7 | c.301C>A p.L101M | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100736978, COSV63165128; called by muse, mutect2, varscan2
- GTF3C2 | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV99272889; called by muse, mutect2, varscan2
- HEXIM1 | c.276G>C p.Q92H | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV60177398; called by muse, mutect2, varscan2
- HPGDS | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0.036); catalogued as COSV99755800; called by muse, mutect2, varscan2
- HSPA12B | c.1224C>G p.I408M | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99422262; called by muse, mutect2, varscan2
- HYDIN | c.2032G>T p.E678* | Nonsense Mutation (SNP) | VAF 22/82 reads (27%) | catalogued as COSV99863585; called by muse, mutect2, varscan2
- IFI16 | c.1819G>C p.E607Q (on ENST00000295809 / NM_001364867.2; = p.E551Q on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.956); catalogued as COSV99857705; called by muse, mutect2, varscan2
- IFNAR2 | c.1363G>C p.E455Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as COSV51618016, COSV99270047; called by muse, mutect2, varscan2
- IFNL1 | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs369965543, COSV100373654; called by muse, mutect2, varscan2
- IFT122 | c.122C>G p.S41C | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as COSV99959445; called by muse, mutect2, varscan2
- IGF2R | c.5536G>C p.E1846Q | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as COSV100807552; called by muse, mutect2
- IGFL3 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as COSV100407897; called by muse, mutect2, varscan2
- INSM1 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV100044740; called by muse, mutect2, varscan2
- INTS5 | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.923); catalogued as COSV100399671; called by muse, mutect2, varscan2
- ISLR | c.49C>G p.Q17E | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as COSV99997381; called by muse, mutect2, varscan2
- ITLN1 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100406262; called by muse, mutect2
- ITPKC | c.1005G>C p.E335D | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as COSV99648823; called by muse, mutect2
- KANSL1L | c.2299G>A p.E767K | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99910648; called by muse, mutect2, varscan2
- KCNE3 | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.08); catalogued as COSV100035635, COSV59552085; called by muse, mutect2, varscan2
- KCNH2 | c.2861G>T p.R954L | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.206); catalogued as COSV100060264; called by muse, mutect2
- KCNH6 | c.478C>G p.H160D | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV100121120; called by muse, mutect2, varscan2
- KCNJ2 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.861); catalogued as COSV99696412; called by muse, mutect2, varscan2
- KCNQ4 | c.1716G>A p.M572I | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100714354; called by muse, varscan2
- KIAA0319L | c.1259C>G p.S420C | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1171269759, COSV100357439; called by muse, mutect2, varscan2
- KIF1B | c.883-1G>A p.X295_splice (on ENST00000377086 / NM_001365952.1; = p.X289_splice on NM_015074.3) | Splice Site (SNP) | VAF 20/41 reads (49%) | catalogued as COSV55813127, COSV99823533; called by muse, mutect2, varscan2
- KIF24 | c.1915C>G p.Q639E | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs747589405, COSV100799200; called by muse, mutect2, varscan2
- KIF7 | c.3797G>A p.R1266Q | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs144301755; called by muse, mutect2, varscan2
- KLHL12 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 22/29 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV66127977; called by muse, mutect2, varscan2
- KMT2B | c.5718C>A p.F1906L | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.168); catalogued as COSV99719843; called by muse, mutect2, varscan2
- KMT2D | c.9962G>A p.R3321Q | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.166); catalogued as rs753081311, COSV56472059; called by muse, mutect2, varscan2
- KNL1 | c.6334C>G p.Q2112E (on ENST00000346991 / NM_170589.5; = p.Q2086E on NM_144508.5) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.946); catalogued as rs777307968, COSV100706627; called by muse, varscan2
- KRT72 | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV99537333; called by muse, mutect2, varscan2
- KRT76 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV100196285; called by muse, mutect2
- KRTAP19-1 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs371788350, COSV66861122; called by muse, mutect2, varscan2
- LENG8 | c.824G>C p.G275A | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV100457648; called by muse, mutect2, varscan2
- LHX5 | c.995G>A p.G332D | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV99922486; called by muse, mutect2, varscan2
- LIG1 | c.2738C>G p.S913C | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as rs1399351101, COSV99619031; called by muse, mutect2, varscan2
- LIG3 | c.469dup p.I157Nfs*16 | Frame Shift Ins (INS) | VAF 15/34 reads (44%) | catalogued as rs745989900; called by mutect2, varscan2
- LILRB5 | c.881G>A p.R294K | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); catalogued as COSV100300502; called by muse, mutect2, varscan2
- LIM2 | c.194G>T p.R65L (on ENST00000596399 / NM_001161748.2; = p.R107L on NM_030657.4) | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); catalogued as rs757069172, COSV55741857, COSV99702389; called by muse, mutect2, varscan2
- LIPG | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT tolerated (0.28); PolyPhen benign (0.21); catalogued as rs750648857, COSV54294741; called by muse, mutect2, varscan2
- LOXL2 | c.96T>A p.H32Q | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV101207927; called by muse, mutect2, varscan2
- LRP6 | c.106G>C p.A36P | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV99743545; called by muse, mutect2, varscan2
- LRRC49 | c.2005C>T p.R669C | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as rs371609494, COSV53008263; called by muse, mutect2, varscan2
- MAP3K11 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as rs756165003, COSV100482430, COSV100482566; called by muse, mutect2, varscan2
- MAP3K3 | c.875G>A p.R292K | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV100675558; called by muse, varscan2
- MAPKBP1 | c.194C>G p.A65G | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV99529683; called by muse, mutect2, varscan2
- MBTPS1 | c.1417C>G p.Q473E | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0.05); catalogued as COSV100597646; called by muse, mutect2, varscan2
- MEGF6 | c.3771C>G p.N1257K | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV99620583; called by muse, mutect2, varscan2
- METTL3 | c.52C>G p.L18V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100074483; called by muse, mutect2
- MFSD8 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.35); PolyPhen benign (0.054); catalogued as rs778902510, COSV99614458; called by muse, mutect2, varscan2
- MIOS | c.1614C>G p.I538M | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as rs529813614, COSV100402820; called by muse, mutect2, varscan2
- MMEL1 | c.1169A>T p.Y390F | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.218); catalogued as COSV99983951; called by muse, mutect2, varscan2
- MMP10 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99666595; called by muse, mutect2
- MPEG1 | c.2071G>C p.E691Q | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV99915549; called by muse, mutect2, varscan2
- MPHOSPH8 | c.2281G>C p.D761H | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100825150; called by muse, mutect2, varscan2
- MPL | c.1552C>T p.P518S | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.134); catalogued as COSV100991616; called by muse, mutect2, varscan2
- MRPL53 | c.72G>T p.E24D | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as COSV50688407, COSV99252164; called by muse, mutect2, varscan2
- MSANTD2 | c.1600G>C p.E534Q (on ENST00000374979 / NM_001308027.2; = p.E482Q on NM_024631.4) | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV53450915, COSV99515615; called by muse, mutect2, varscan2
- MUC16 | c.40214G>C p.G13405A | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.981); catalogued as COSV101109932; called by muse, mutect2, varscan2
- MUC5AC | c.14850G>C p.Q4950H | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.962); catalogued as rs1265722680, COSV100611478; called by muse, mutect2, varscan2
- MUS81 | c.390C>G p.Y130* | Nonsense Mutation (SNP) | VAF 3/31 reads (10%) | catalogued as COSV100337274; called by muse, mutect2
- MYO5A | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV100697771; called by muse, mutect2, varscan2
- NDUFAF6 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 84/306 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.149); catalogued as COSV99712788; called by muse, mutect2, varscan2
- NDUFV2 | c.691C>G p.L231V | Missense Mutation (SNP) | VAF 53/97 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as COSV100041509, COSV50824277; called by muse, mutect2, varscan2
- NEB | c.3838C>T p.Q1280* | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | catalogued as rs1044151784, COSV50805935, COSV99424311; called by muse, mutect2, varscan2
- NEDD4 | c.1553G>C p.R518T (on ENST00000508342 / NM_001284338.1; = p.R99T on NM_006154.4) | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100163791; called by muse, mutect2, varscan2
- NETO1 | c.1079C>A p.S360Y | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100198932, COSV55004072; called by muse, mutect2, varscan2
- NEURL3 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as COSV100182437; called by muse, mutect2, varscan2
- NEURL4 | c.3185C>G p.T1062S | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.482); catalogued as rs1416693586, COSV100223050; called by muse, mutect2
- NLRC5 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as COSV99347549; called by muse, mutect2, varscan2
- NLRC5 | c.4798G>C p.E1600Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV99347554; called by muse, mutect2, varscan2
- NOL11 | c.1176G>T p.Q392H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99475106; called by muse, mutect2, varscan2
- NOS2 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as rs766602194, COSV58223062; called by muse, mutect2, varscan2
- NUP210 | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as rs372026570; called by muse, mutect2, varscan2
- NYAP2 | c.1129G>A p.G377R | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs538675320, COSV99797077; called by muse, mutect2, varscan2
- OBSCN | c.3970G>C p.D1324H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372433145; called by muse, mutect2, varscan2
- OPN1LW | c.327C>G p.I109M | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100886909; called by muse, mutect2, varscan2
- OR1J4 | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); catalogued as COSV61589530; called by muse, mutect2, varscan2
- OR52B6 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100798500; called by muse, mutect2, varscan2
- OR52M1 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV100798610, COSV64172790; called by muse, mutect2, varscan2
- OR5AN1 | c.312C>G p.I104M | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs1565053197, COSV100004337, COSV100004370; called by mutect2, varscan2
- OR8H1 | c.509C>G p.S170* | Nonsense Mutation (SNP) | VAF 17/29 reads (59%) | catalogued as COSV100476953, COSV100477177; called by muse, mutect2, varscan2
- OSCP1 | c.648C>T p.I216= (on ENST00000356637 / NM_001330493.1; = p.I206= on NM_145047.5) | Splice Region (SNP) | VAF 13/43 reads (30%) | catalogued as COSV99347353; called by muse, mutect2, varscan2
- OSMR | c.2719G>A p.E907K | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as COSV99952869; called by muse, mutect2, varscan2
- PABPN1L | c.651C>G p.I217M | Missense Mutation (SNP) | VAF 67/106 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1284085249, COSV99967664; called by muse, mutect2, varscan2
- PANK2 | c.1435G>A p.E479K (on ENST00000316562 / NM_153638.3; = p.E188K on NM_024960.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.165); catalogued as COSV100262360; called by muse, mutect2, varscan2
- PASD1 | c.974C>A p.P325Q | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.009); catalogued as COSV64856923; called by muse, mutect2, varscan2
- PCBP2 | c.930C>G p.I310M (on ENST00000439930 / NM_001128911.2; = p.I311M on NM_005016.6) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100827648; called by muse, varscan2
- PCDHB2 | c.2193G>C p.E731D | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.039); catalogued as COSV99165464; called by muse, mutect2, varscan2
- PCDHB7 | c.2179G>C p.E727Q | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.178); catalogued as COSV50761423; called by muse, mutect2, varscan2
- PCNA | c.199G>C p.A67P | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.432); catalogued as COSV100996244; called by muse, mutect2, varscan2
- PCOLCE | c.113G>C p.G38A | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99575427; called by muse, mutect2, varscan2
- PDCD11 | c.3682G>C p.E1228Q | Missense Mutation (SNP) | VAF 37/38 reads (97%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as COSV100874360; called by muse, mutect2, varscan2
- PDZD2 | c.4789G>C p.E1597Q | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99225417; called by muse, mutect2, varscan2
- PELP1 | c.2842G>C p.E948Q | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.14); catalogued as COSV99343014; called by muse, mutect2, varscan2
- PHKG1 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99305166; called by muse, mutect2, varscan2
- PI4K2B | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as COSV99335519; called by muse, mutect2, varscan2
- PIWIL3 | c.931C>T p.R311* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as rs752998059, COSV100177673; called by muse, mutect2, varscan2
- PLA2G4A | c.1358G>C p.G453A | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100820581; called by muse, mutect2
- PLA2G4F | c.2350G>C p.E784Q | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as COSV99300708, COSV99300709; called by muse, mutect2, varscan2
- PLSCR1 | c.837C>G p.I279M | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs377240309, COSV100678418; called by muse, mutect2, varscan2
- PLXNC1 | c.1311C>G p.I437M | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99313320; called by muse, mutect2, varscan2
- PODXL | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.716); catalogued as rs1342084354, COSV100539542; called by muse, mutect2
- PPM1B | c.1210A>T p.R404W | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV99175816; called by muse, mutect2, varscan2
- PPP2R1A | c.1756C>T p.L586= | Splice Region (SNP) | VAF 23/55 reads (42%) | catalogued as COSV100436312, COSV59047894; called by muse, mutect2, varscan2
- PRDM14 | c.1640C>T p.S547L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as COSV99400253; called by muse, mutect2, varscan2
- PRDM16 | c.3538G>A p.E1180K | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (0.4); PolyPhen benign (0.054); catalogued as rs763267613, COSV99577140; called by muse, mutect2, varscan2
- PRKCA | c.650C>G p.S217C | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.022); catalogued as rs140400644, COSV99435911; called by muse, mutect2, varscan2
- PRKDC | c.2430G>C p.K810N | Missense Mutation (SNP) | VAF 68/99 reads (69%) | SIFT tolerated (0.21); PolyPhen benign (0.142); catalogued as COSV100041080; called by muse, mutect2, varscan2
- PTCD1 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs147029104, COSV52862689; called by muse, mutect2, varscan2
- PURA | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 7/12 reads (58%) | catalogued as COSV100495744; called by muse, mutect2, varscan2
- PWWP2A | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.177); catalogued as COSV100193955; called by muse, mutect2, varscan2
- RARG | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV99914118; called by muse, mutect2
- RBBP8 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.23); catalogued as COSV100506993, COSV100507454; called by muse, mutect2, varscan2
- RCBTB2 | c.1483C>A p.L495M | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100749597, COSV60651469; called by mutect2, varscan2
- RECQL4 | c.1420G>C p.E474Q | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as COSV99467709; called by muse, mutect2, varscan2
- REV3L | c.7767G>A p.M2589I | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV100725311; called by muse, mutect2, varscan2
- RGS3 | c.2650G>C p.E884Q (on ENST00000350696 / NM_001282923.2; = p.E603Q on NM_130795.4) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs1476529562, COSV100636797; called by muse, mutect2, varscan2
- RHOBTB1 | c.1021C>T p.P341S | Missense Mutation (SNP) | VAF 29/35 reads (83%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV61958150; called by muse, mutect2, varscan2
- RIBC1 | c.397T>G p.Y133D | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.158); catalogued as COSV99395008; called by muse, mutect2, varscan2
- RNF17 | c.1307C>T p.S436L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99693484; called by muse, mutect2, varscan2
- RNF180 | c.186G>C p.M62I | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.292); catalogued as rs373363351, COSV99684765; called by muse, mutect2, varscan2
- RNF39 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.2); PolyPhen benign (0.14); catalogued as COSV99748407; called by muse, varscan2
- RYR2 | c.5191G>C p.E1731Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV100771017, COSV63679023; called by muse, mutect2, varscan2
- SASH1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.651); catalogued as rs756740212, COSV100821257; called by muse, mutect2, varscan2
- SCRN1 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as rs1438793959, COSV54128956; called by muse, mutect2, varscan2
- SDK2 | c.6325G>A p.E2109K | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV66199284; called by muse, mutect2, varscan2
- SEPTIN12 | c.915C>G p.I305M | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV99190783; called by muse, mutect2, varscan2
- SETD2 | c.6929C>G p.S2310* | Nonsense Mutation (SNP) | VAF 8/16 reads (50%) | catalogued as COSV100339226; called by muse, mutect2, varscan2
- SFN | c.177G>C p.W59C | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100212833; called by muse, mutect2, varscan2
- SFTPA2 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV100958794; called by muse, mutect2, varscan2
- SLC25A20 | c.421C>G p.Q141E | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV59802266; called by muse, mutect2, varscan2
- SLC26A8 | c.2653G>A p.E885K | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as COSV100839507; called by muse, mutect2, varscan2
- SLC36A4 | c.813G>T p.K271N | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as COSV58395197; called by muse, mutect2, varscan2
- SORBS2 | c.1933C>T p.H645Y | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); catalogued as COSV99511352; called by muse, mutect2, varscan2
- SPACA1 | c.232G>C p.E78Q | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.923); catalogued as COSV52758941, COSV99389565; called by muse, mutect2, varscan2
- SPEN | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751080105, COSV101005243; called by muse, mutect2, varscan2
- SRBD1 | c.2828C>G p.S943C | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.423); catalogued as COSV99765147; called by muse, mutect2, varscan2
- STARD3NL | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1194155105, COSV99151590; called by muse, mutect2, varscan2
- STIM2 | c.1940C>G p.S647C | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV99402808; called by muse, mutect2, varscan2
- STKLD1 | c.848C>T p.S283L | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs372995558, COSV100912031; called by muse, mutect2, varscan2
- STX10 | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV99460249; called by muse, mutect2
- SV2A | c.586G>T p.D196Y | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100975177; called by muse, mutect2
- SVOPL | c.664A>G p.I222V (on ENST00000419765; = p.I70V on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.824); catalogued as COSV99939424; called by muse, mutect2, varscan2
- SYNE1 | c.16078C>T p.L5360F (on ENST00000367255 / NM_182961.4; = p.L5289F on NM_033071.3) | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as rs780563237, COSV99567803; called by muse, mutect2, varscan2
- SYNE1 | c.2401G>T p.E801* (on ENST00000367255 / NM_182961.4; = p.E808* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 10/29 reads (34%) | catalogued as COSV99567808; called by muse, mutect2, varscan2
- SYT3 | c.1359C>G p.I453M | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100144163; called by muse, mutect2, varscan2
- TAF10 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as COSV100196206; called by muse, varscan2
- TAOK2 | c.2938C>A p.Q980K | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.101); catalogued as COSV54240306; called by muse, mutect2
- TBXT | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.541); catalogued as COSV51616035, COSV51619673, COSV99752603; called by muse, mutect2, varscan2
- TCF7L2 | c.1348C>T p.L450F (on ENST00000355995 / NM_001367943.1; = p.L427F on NM_030756.5) | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.149); catalogued as COSV99525966; called by muse, mutect2, varscan2
- TENM3 | c.3955G>C p.G1319R | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101305187; called by muse, mutect2, varscan2
- TESK2 | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100517442; called by muse, mutect2, varscan2
- TICRR | c.3500C>T p.S1167L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.24); catalogued as rs369691167; called by muse, mutect2, varscan2
- TLX3 | c.512C>G p.T171R | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99740672; called by muse, mutect2, varscan2
- TMEM106B | c.686+1G>A p.X229_splice | Splice Site (SNP) | VAF 18/44 reads (41%) | catalogued as COSV101188833; called by muse, mutect2, varscan2
- TNNI2 | c.288G>A p.M96I | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV99425504; called by muse, mutect2, varscan2
- TNRC6C | c.2773C>T p.Q925* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as COSV100050106; called by muse, mutect2, varscan2
- TOMM70 | c.136G>C p.G46R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV52522596, COSV99424401; called by muse, mutect2
- TOP2A | c.3526G>T p.E1176* | Nonsense Mutation (SNP) | VAF 12/47 reads (26%) | catalogued as COSV101396237; called by muse, mutect2, varscan2
- TRAM2 | c.57C>G p.I19M | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99480237; called by muse, mutect2, varscan2
- TRIML2 | c.902C>T p.S301L | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV100456118; called by muse, mutect2, varscan2
- TRPC1 | c.1123C>T p.Q375* (on ENST00000476941 / NM_001251845.2; = p.Q341* on NM_003304.4) | Nonsense Mutation (SNP) | VAF 14/104 reads (13%) | catalogued as rs1435337701, COSV99858266; called by muse, mutect2, varscan2
- TSEN34 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs374974634, COSV99824877; called by muse, mutect2
- TSNAXIP1 | c.1644G>C p.Q548H | Missense Mutation (SNP) | VAF 59/85 reads (69%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV99535165; called by muse, mutect2, varscan2
- TTC24 | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.494); catalogued as COSV100964339; called by muse, mutect2, varscan2
- TTLL5 | c.3618G>C p.Q1206H | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.254); catalogued as COSV100090628; called by muse, mutect2, varscan2
- TUBB4B | c.282G>C p.Q94H | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.013); catalogued as COSV61115579; called by muse, mutect2, varscan2
- UBR2 | c.3565C>G p.Q1189E | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.397); catalogued as COSV100867464; called by muse, mutect2, varscan2
- UHRF2 | c.1395G>A p.V465= | Splice Region (SNP) | VAF 27/61 reads (44%) | catalogued as COSV99436824; called by muse, mutect2, varscan2
- ULK1 | c.1631C>G p.S544C | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.635); catalogued as rs150697369, COSV58859599; called by muse, mutect2, varscan2
- USP4 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV99649415; called by muse, mutect2
- UTP20 | c.3403G>C p.D1135H | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV99881831; called by muse, mutect2, varscan2
- VIRMA | c.2263G>C p.D755H | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); catalogued as COSV99888619; called by muse, mutect2, varscan2
- VIRMA | c.487G>T p.D163Y | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.731); catalogued as COSV99888625, COSV99888812; called by muse, mutect2, varscan2
- WAC | c.125G>C p.R42T | Missense Mutation (SNP) | VAF 45/52 reads (87%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV100611058; called by muse, mutect2, varscan2
- WDPCP | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV99705623; called by muse, mutect2, varscan2
- WDR81 | c.3416C>T p.S1139L (on ENST00000409644 / NM_001163809.2; = p.S88L on NM_152348.4) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100488978; called by muse, mutect2, varscan2
- XPO1 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV68945933; called by muse, mutect2
- XRN1 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV53811198; called by muse, mutect2, varscan2
- YWHAZ | c.505G>T p.G169C | Missense Mutation (SNP) | VAF 63/95 reads (66%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100782574; called by muse, mutect2, varscan2
- ZC3H10 | c.128G>C p.R43T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99230536; called by muse, mutect2, varscan2
- ZC3H7B | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as rs1040884403, COSV100687431; called by muse, mutect2, varscan2
- ZKSCAN7 | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.38); catalogued as COSV99837648; called by muse, mutect2, varscan2
- ZMYM5 | c.1867G>T p.E623* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV100562728; called by muse, mutect2
- ZNF25 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as COSV100224662; called by muse, mutect2, varscan2
- ZNF345 | c.1142G>T p.S381I | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.781); catalogued as rs768258870, COSV100080148, COSV100080328; called by muse, mutect2, varscan2
- ZNF425 | c.207C>G p.I69M | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as COSV100955492; called by muse, mutect2, varscan2
- ZNF493 | c.1228A>T p.I410F | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100828736; called by muse, mutect2, varscan2
- ZNF644 | c.2896C>T p.P966S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1330049244, COSV100494533; called by muse, mutect2, varscan2
- ZNF676 | c.1296A>T p.K432N (on ENST00000650058; = p.K400N on NM_001001411.3) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101236242; called by muse, varscan2
- ZNF700 | c.1095G>C p.K365N | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); catalogued as COSV99583592; called by muse, mutect2, varscan2
- OXCT1 | c.94T>C p.F32L | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2
- PRAMEF15 | c.219G>C p.K73N | Missense Mutation (SNP) | VAF 25/261 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- SMARCA1 | c.2969_2970del p.Q990Lfs*9 | Frame Shift Del (DEL) | VAF 9/24 reads (38%) | called by mutect2, pindel, varscan2
- TRAV8-2 | c.89T>G p.V30G | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ZNF26 | c.1333C>T p.Q445* | Nonsense Mutation (SNP) | VAF 38/86 reads (44%) | called by muse, mutect2, varscan2
- ABCA12 | c.102C>T p.V34= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV99790364; called by muse, mutect2, varscan2
- ABCB8 | c.1284C>G p.L428= (on ENST00000297504 / NM_001282291.2; = p.L411= on NM_007188.5) | Silent (SNP) | VAF 34/78 reads (44%) | catalogued as COSV99874542; called by muse, mutect2, varscan2
- ABHD5 | c.198G>A p.L66= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV99185483; called by muse, mutect2, varscan2
- ABRAXAS1 | c.804G>A p.K268= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV55030618; called by muse, mutect2
- ADGRV1 | c.4791G>A p.E1597= | Silent (SNP) | VAF 35/63 reads (56%) | catalogued as COSV101316106, COSV101316554; called by muse, mutect2, varscan2
- ANAPC2 | c.2145C>G p.V715= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV100119118; called by muse, mutect2
- APOB | c.9441G>A p.L3147= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs1050626606, COSV99266099; called by muse, mutect2, varscan2
- ARFGEF1 | c.34C>T p.L12= | Silent (SNP) | VAF 27/135 reads (20%) | catalogued as rs1341367015, COSV99142728; called by muse, varscan2
- ARHGAP45 | c.984C>T p.V328= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV100490845; called by muse, mutect2, varscan2
- ARID1A | c.1983G>A p.V661= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV100252061; called by muse, mutect2, varscan2
- ARID1B | c.6228C>A p.L2076= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as COSV99269985; called by muse, mutect2, varscan2
- ASTN2 | c.2643C>G p.L881= (on ENST00000313400 / NM_001365069.1; = p.L830= on NM_014010.5) | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100528281; called by muse, mutect2, varscan2
- ATR | c.5325G>A p.V1775= | Silent (SNP) | VAF 17/87 reads (20%) | catalogued as COSV100638300; called by muse, mutect2, varscan2
- BMERB1 | c.204C>T p.V68= | Silent (SNP) | VAF 22/142 reads (15%) | catalogued as COSV100253071; called by muse, mutect2, varscan2
- BPIFB4 | c.516G>A p.L172= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as COSV100971553; called by muse, mutect2, varscan2
- BRSK1 | c.2140C>T p.L714= | Silent (SNP) | VAF 28/55 reads (51%) | catalogued as COSV100442376; called by muse, mutect2, varscan2
- C1QTNF5 | c.450C>G p.V150= | Silent (SNP) | VAF 26/55 reads (47%) | catalogued as rs1216321606, COSV100264842; called by muse, mutect2, varscan2
- CAMSAP3 | c.3123G>A p.L1041= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs780550825, COSV99351013; called by muse, mutect2, varscan2
- CARNS1 | c.2034C>G p.L678= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as COSV100322058; called by muse, mutect2, varscan2
- CARNS1 | c.2436C>T p.I812= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as rs751093192, COSV100322065; called by muse, mutect2, varscan2
- CENPC | c.1275C>T p.F425= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as COSV99894059; called by muse, mutect2, varscan2
- CFAP58 | c.1980G>A p.K660= | Silent (SNP) | VAF 36/41 reads (88%) | catalogued as COSV100866120; called by muse, mutect2, varscan2
- COBL | c.1248C>T p.I416= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs760510581, COSV54358248; called by muse, mutect2, varscan2
- CRACDL | c.2559G>A p.L853= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV101194056; called by muse, mutect2, varscan2
- CUL7 | c.2760C>T p.L920= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV99538776; called by muse, varscan2
- DDRGK1 | c.645C>T p.F215= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV100621458; called by muse, mutect2, varscan2
- DMGDH | c.1209C>T p.H403= | Silent (SNP) | VAF 27/56 reads (48%) | catalogued as rs143266258; called by muse, mutect2, varscan2
- DMTN | c.114G>C p.V38= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV99741859; called by muse, mutect2
- DYNC2H1 | c.5436C>T p.F1812= | Silent (SNP) | VAF 33/65 reads (51%) | catalogued as COSV100518691, COSV100518792; called by muse, mutect2, varscan2
- EDEM2 | c.1047C>T p.L349= | Silent (SNP) | VAF 28/51 reads (55%) | catalogued as COSV100993790; called by muse, mutect2, varscan2
- EIF2B2 | c.960C>T p.L320= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as rs759914845, COSV99837695; called by muse, mutect2, varscan2
- EPB41L1 | c.1119C>T p.F373= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV99151096; called by muse, mutect2
- EPHA3 | c.456C>T p.F152= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV100345999; called by muse, mutect2, varscan2
- ESPL1 | c.3222G>A p.V1074= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as COSV99229423; called by muse, mutect2, varscan2
- FAM83A | c.385C>T p.L129= | Silent (SNP) | VAF 72/94 reads (77%) | catalogued as COSV99414330; called by muse, mutect2, varscan2
- FAS | c.459C>A p.I153= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV100570833; called by muse, mutect2, varscan2
- FAT4 | c.13830C>T p.A4610= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs776510562, COSV100628971; called by muse, varscan2
- FNBP4 | c.3024G>A p.L1008= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV99771734; called by muse, mutect2, varscan2
- FOXD4L6 | c.1125G>A p.P375= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as rs1363786290; called by muse, mutect2, varscan2
- FOXK1 | c.984G>C p.L328= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV61068826; called by muse, mutect2, varscan2
- GBA2 | c.945C>T p.S315= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs369520290, COSV100803415; called by muse, mutect2, varscan2
- GMFG | c.69C>T p.F23= | Silent (SNP) | VAF 33/59 reads (56%) | catalogued as rs140200000, COSV53419630, COSV53420009; called by muse, mutect2, varscan2
- GPATCH8 | c.4467C>T p.F1489= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV100132703; called by muse, mutect2, varscan2
- GPR84 | c.1021C>T p.L341= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV99910064; called by muse, mutect2, varscan2
- H2BC15 | c.210C>T p.I70= | Silent (SNP) | VAF 45/148 reads (30%) | catalogued as COSV100357006; called by muse, mutect2, varscan2
- HCFC1 | c.4581G>A p.L1527= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV60077941; called by muse, mutect2, varscan2
- HGSNAT | c.729G>T p.V243= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV101108177; called by muse, mutect2, varscan2
- HK2 | c.1495C>T p.L499= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV99309180; called by muse, mutect2, varscan2
- IL11RA | c.639G>A p.Q213= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as COSV99426512; called by muse, mutect2, varscan2
- INTS5 | c.249G>A p.E83= | Silent (SNP) | VAF 25/45 reads (56%) | catalogued as rs565093633, COSV100399672; called by muse, mutect2, varscan2
- JAKMIP3 | c.438G>C p.G146= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV100059342; called by muse, mutect2, varscan2
- KIF6 | c.2416C>T p.L806= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs779623401, COSV99759249; called by muse, varscan2
- KLHDC7B | c.1464C>T p.I488= (on ENST00000395676; = p.I1129= on NM_138433.5) | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as rs766628610, COSV101192952; called by muse, mutect2, varscan2
- LAMA5 | c.7335C>T p.H2445= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as rs1256811723, COSV99440504; called by muse, mutect2, varscan2
- LAMB2 | c.1869G>T p.L623= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100565287; called by muse, mutect2, varscan2
- LCP2 | c.1486C>T p.L496= | Silent (SNP) | VAF 40/78 reads (51%) | catalogued as COSV99252935; called by muse, mutect2, varscan2
- LPIN2 | c.1611C>T p.S537= | Silent (SNP) | VAF 24/37 reads (65%) | catalogued as rs754391475, COSV99858482; called by muse, mutect2, varscan2
- LRRC3 | c.177C>T p.P59= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs747544847, COSV52399850; called by muse, mutect2, varscan2
- LRRC4B | c.1479G>A p.E493= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as rs539581388, COSV100975952; called by muse, mutect2, varscan2
- LSM7 | c.132C>T p.L44= | Silent (SNP) | VAF 63/140 reads (45%) | catalogued as rs1305972615, COSV99395926; called by muse, mutect2, varscan2
- MAP3K2 | c.1230G>A p.L410= | Silent (SNP) | VAF 20/26 reads (77%) | catalogued as COSV100777235; called by muse, varscan2
- MBNL3 | c.906G>A p.P302= | Silent (SNP) | VAF 30/59 reads (51%) | catalogued as rs912809704, COSV63731782; called by muse, mutect2, varscan2
- MEAF6 | c.543G>C p.L181= (on ENST00000296214 / NM_001270875.3; = p.L191= on NM_022756.6) | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV99952740; called by muse, mutect2, varscan2
- MECP2 | c.984C>T p.L328= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as rs61751442, COSV57654670; ClinVar: benign; called by muse, mutect2, varscan2
- MRPS18B | c.30G>A p.L10= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV52543119, COSV99457761; called by muse, mutect2, varscan2
- NIN | c.4710G>A p.K1570= (on ENST00000382041 / NM_182946.1; = p.K857= on NM_016350.4) | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV99813872; called by muse, mutect2, varscan2
- NLRC5 | c.1314C>G p.L438= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV99347551; called by muse, mutect2, varscan2
- NPC1L1 | c.243C>G p.L81= | Silent (SNP) | VAF 20/29 reads (69%) | catalogued as COSV56924929, COSV56925469; called by muse, mutect2, varscan2
- NWD1 | c.1593G>A p.G531= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV60354247; called by muse, mutect2
- NYNRIN | c.291C>T p.L97= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as COSV101230617; called by muse, mutect2, varscan2
- OR1E2 | c.312C>T p.F104= | Silent (SNP) | VAF 35/64 reads (55%) | catalogued as rs1270399780, COSV99943448; called by muse, mutect2, varscan2
- OR9I1 | c.72G>A p.E24= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV100110083, COSV56927242; called by muse, mutect2, varscan2
- P2RX6 | c.702C>T p.F234= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV100298745; called by muse, mutect2, varscan2
- PANK4 | c.357C>T p.V119= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV101022461; called by muse, mutect2, varscan2
- PCDHA6 | c.705G>T p.V235= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV100972354; called by muse, mutect2, varscan2
- PCDHGA9 | c.2358G>A p.E786= | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as COSV99539243; called by muse, mutect2, varscan2
- PCNT | c.483C>T p.V161= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV100855634; called by muse, mutect2, varscan2
- PLEKHG3 | c.3429G>C p.P1143= (on ENST00000394691; = p.P1199= on NM_001308147.2) | Silent (SNP) | VAF 44/76 reads (58%) | catalogued as COSV99906698; called by muse, mutect2, varscan2
- PPFIA3 | c.2178A>G p.R726= | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as COSV100494740; called by muse, mutect2, varscan2
- PPP1R15A | c.1809G>C p.L603= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99566100; called by muse, mutect2
- PRR5 | c.351G>A p.E117= (on ENST00000336985 / NM_181333.4; = p.E108= on NM_015366.4) | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV50063488, COSV99134457; called by muse, mutect2, varscan2
- PRSS55 | c.504C>G p.L168= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV60808840, COSV60809562; called by muse, mutect2, varscan2
- PSMB7 | c.597C>T p.S199= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs754799838, COSV99412937; called by muse, mutect2, varscan2
- PSMD2 | c.816C>T p.L272= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs1253539089, COSV100031833; called by muse, mutect2, varscan2
- PTBP1 | c.1032C>G p.L344= (on ENST00000349038 / NM_031991.4; = p.L370= on NM_002819.5) | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as COSV100608803; called by muse, mutect2, varscan2
- PTGIR | c.363G>C p.L121= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs1485816594, COSV99354998; called by muse, mutect2, varscan2
- RAC2 | c.330C>T p.I110= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV99969508; called by muse, mutect2, varscan2
- RASL10B | c.375C>T p.I125= | Silent (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- RBFOX2 | c.573C>T p.F191= (on ENST00000438146 / NM_001349995.2; = p.F121= on NM_014309.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV99455505; called by muse, mutect2, varscan2
- RFC1 | c.1860G>A p.K620= | Silent (SNP) | VAF 27/52 reads (52%) | catalogued as COSV100567785, COSV62898451; called by muse, mutect2, varscan2
- RPS6KA2 | c.1605G>A p.P535= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs190233367; called by muse, mutect2, varscan2
- RUSC1 | c.252G>A p.R84= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV99429933; called by muse, mutect2, varscan2
- SAFB | c.129G>A p.L43= | Silent (SNP) | VAF 44/82 reads (54%) | catalogued as COSV99385808; called by muse, varscan2
- SEMA5B | c.813G>A p.P271= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as rs548370011, COSV99532198; called by muse, mutect2, varscan2
- SLC27A4 | c.81C>T p.F27= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as COSV100056609; called by muse, mutect2, varscan2
- SLC34A2 | c.402C>T p.F134= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs1437120772, COSV101158382; called by muse, mutect2, varscan2
- SNAPC4 | c.267G>A p.L89= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV100047356; called by muse, mutect2, varscan2
- STARD10 | c.48C>T p.V16= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV100600456; called by muse, mutect2, varscan2
- TACC2 | c.6819G>A p.K2273= (on ENST00000334433; = p.K351= on NM_006997.4) | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as COSV99587181; called by muse, mutect2, varscan2
- TBCK | c.2511C>T p.L837= (on ENST00000273980 / NM_001163436.4; = p.L774= on NM_033115.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs141129535; called by muse, mutect2, varscan2
- TBX18 | c.1125C>G p.L375= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as rs752247587, COSV100858531; called by muse, mutect2, varscan2
- TDRD3 | c.949C>T p.L317= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV99540596; called by muse, mutect2, varscan2
- TEP1 | c.6312C>T p.A2104= | Silent (SNP) | VAF 26/26 reads (100%) | catalogued as COSV99402600; called by muse, mutect2, varscan2
- TRIM39 | c.528G>A p.E176= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV100935790; called by muse, mutect2, varscan2
- TRMU | c.915G>A p.L305= | Silent (SNP) | VAF 21/41 reads (51%) | catalogued as COSV99324589; called by muse, mutect2
- TSNAXIP1 | c.1164G>A p.E388= | Silent (SNP) | VAF 35/53 reads (66%) | catalogued as COSV99535164; called by muse, mutect2, varscan2
- TUBGCP6 | c.1929C>T p.Y643= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs201860796, COSV99955780; called by muse, mutect2, varscan2
- UNC79 | c.3510T>C p.F1170= (on ENST00000393151 / NM_001346218.2; = p.F993= on NM_020818.5) | Silent (SNP) | VAF 44/48 reads (92%) | catalogued as COSV99828313; called by muse, mutect2, varscan2
- UTRN | c.8586C>G p.A2862= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV100838630; called by muse, mutect2, varscan2
- WASHC1 | c.876C>G p.L292= | Silent (SNP) | VAF 15/178 reads (8%) | called by muse, varscan2
- XRN1 | c.3531C>G p.R1177= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as rs1393435784, COSV99378213; called by muse, mutect2, varscan2
- YIPF4 | c.111C>G p.V37= | Silent (SNP) | VAF 44/65 reads (68%) | catalogued as COSV99479914; called by muse, mutect2, varscan2
- ZBTB21 | c.1587G>A p.L529= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as COSV100177173; called by muse, mutect2, varscan2
- ZFP82 | c.891G>C p.L297= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as rs1431895859, COSV101089129; called by muse, mutect2, varscan2
- ZGLP1 | c.678C>G p.L226= | Silent (SNP) | VAF 32/54 reads (59%) | catalogued as rs1471226134, COSV67059701; called by muse, mutect2, varscan2
- ZNF133 | c.1900C>T p.L634= (on ENST00000316358 / NM_001352454.2; = p.L633= on NM_003434.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs756880004, COSV100315530; called by muse, mutect2, varscan2
- ZNF282 | c.1935C>A p.L645= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV100021714, COSV50479994; called by muse, mutect2, varscan2
- ZXDC | c.1215G>C p.L405= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV100306509; called by muse, mutect2, varscan2
- AL136439.1 | chr13:27665774 G>C | 3'Flank (SNP) | VAF 17/41 reads (41%) | catalogued as COSV101294873; called by muse, mutect2, varscan2
- C9orf85 | c.323+1156G>A | Intron (SNP) | VAF 21/47 reads (45%) | catalogued as rs373529335; called by muse, mutect2, varscan2
- CCDC115 | c.-2C>T | 5'UTR (SNP) | VAF 11/38 reads (29%) | catalogued as rs925361476, COSV52093493; called by muse, mutect2, varscan2
- DST-AS1 | n.139+7403C>G | Intron (SNP) | VAF 11/37 reads (30%) | catalogued as COSV100880898, COSV66097045; called by muse, mutect2, varscan2
- GFOD1 | c.253+16761A>T | Intron (SNP) | VAF 35/36 reads (97%) | catalogued as COSV101014543; called by muse, mutect2, varscan2
- LINC00922 | n.805C>T | RNA (SNP) | VAF 12/19 reads (63%) | called by muse, mutect2, varscan2
- OR4F17 | c.-2C>G | 5'UTR (SNP) | VAF 63/554 reads (11%) | catalogued as COSV100535561; called by muse, mutect2, varscan2
- RUSC1 | c.-87+266C>T | Intron (SNP) | VAF 28/52 reads (54%) | catalogued as COSV99429932; called by muse, mutect2, varscan2
- SNX29P2 | n.766G>T | RNA (SNP) | VAF 41/101 reads (41%) | called by muse, mutect2, varscan2
- SNX29P2 | n.1016G>A | RNA (SNP) | VAF 29/63 reads (46%) | called by muse, mutect2, varscan2
- SSPOP | n.7562G>A | RNA (SNP) | VAF 14/61 reads (23%) | catalogued as COSV100022621; called by muse, mutect2, varscan2
- Y_RNA | chr7:74897812 G>T | 3'Flank (SNP) | VAF 27/225 reads (12%) | called by muse, varscan2
- ZSCAN32 | c.839-933C>G | Intron (SNP) | VAF 14/21 reads (67%) | catalogued as COSV100514418; called by muse, mutect2, varscan2
